Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6802, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6802-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Stomach
Tumor size: 8 x 5 x 1 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Adjacent structures (specify) - lesser omentum
Lymph nodes: 2/3 positive for metastasis (Intraabdominal 2/3)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 96e62d6e-a813-4247-a642-6c77b4da6843 (TCGA-BR-6802.4A454E20-EC0E-4DBF-8E14-9A451DDBA4AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).